Somatic mutation profile of tumor specimen TCGA-CQ-6218-01A (aliquot TCGA-CQ-6218-01A-11D-1912-08) from TCGA case TCGA-CQ-6218, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 52.3 years (19,096 days).
Specimen TCGA-CQ-6218-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ecf7c16-e4ea-41e3-87a2-6b3316096bda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6218-10A (Blood Derived Normal), aliquot TCGA-CQ-6218-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/178c2716-c283-418b-9dcc-a046fed3def0

The open-access MAF lists 144 somatic variants for this specimen: 93 protein-altering or splice-affecting, 46 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 46, Nonsense Mutation 12, Frame Shift Del 3, RNA 3, Splice Site 2, Intron 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.653T>G p.V218G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555525743, COSV52690974, COSV52712839, COSV52761003; ClinVar: uncertain significance; called by muse, varscan2
- TP53 | c.582del p.I195Sfs*52 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as rs1567552031, COSV52772013, COSV52864400, COSV53143214; ClinVar: pathogenic; called by pindel, varscan2
- ABHD15 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs374284598, COSV56196215; called by muse, mutect2, varscan2
- ABLIM1 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99521807; called by muse, mutect2, varscan2
- AC136428.1 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV101434964; called by muse, mutect2, varscan2
- ACVR2A | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV99604321; called by muse, mutect2
- ADORA1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV100526321; called by muse, mutect2, varscan2
- AFF2 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs781936077, COSV99663170, COSV99665969; called by muse, mutect2, varscan2
- AFM | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.666); catalogued as COSV99888703; called by muse, varscan2
- ASAH1 | c.801C>G p.F267L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV100025635; called by muse, mutect2, varscan2
- ATG2B | c.5853A>G p.I1951M | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99952014; called by muse, mutect2, varscan2
- ATP2A1 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.136); catalogued as COSV100706942; called by muse, mutect2, varscan2
- ATP8A2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54943466, COSV99683072; called by muse, mutect2, varscan2
- ATR | c.6798G>C p.M2266I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV100638006, COSV63388530; called by muse, mutect2, varscan2
- BAZ2B | c.3301C>T p.R1101* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV54275171; called by muse, mutect2, varscan2
- C17orf97 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.007); catalogued as rs200834723; called by muse, varscan2
- C6orf118 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57812422; called by muse, mutect2, varscan2
- C7 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100495673, COSV57471168; called by muse, mutect2, varscan2
- CELSR3 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs199769009, COSV50951729; called by muse, mutect2, varscan2
- CFAP47 | c.2154A>C p.R718S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV99934828; called by muse, mutect2, varscan2
- CHUK | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100957058, COSV64917544; called by muse, mutect2, varscan2
- CLVS2 | c.123G>C p.R41S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.591); catalogued as COSV99252502; called by muse, mutect2, varscan2
- CPT1B | c.1375C>G p.L459V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs1317553931, COSV100376590; called by muse, mutect2
- CREB3L3 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as COSV99314054; called by muse, mutect2, varscan2
- CSMD3 | c.4337A>T p.E1446V (on ENST00000297405 / NM_001363185.1; = p.E1342V on NM_052900.3) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV99831023; called by muse, mutect2, varscan2
- DDX53 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as COSV100028858; called by muse, mutect2, varscan2
- DNHD1 | c.11691T>G p.I3897M | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV99599837; called by muse, mutect2, varscan2
- DNM3 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 27/122 reads (22%) | catalogued as COSV100798007; called by muse, mutect2, varscan2
- DOCK5 | c.5425G>A p.D1809N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.135); catalogued as COSV99376634; called by muse, mutect2, varscan2
- DRAM2 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as COSV54416183; called by muse, varscan2
- EPHB3 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs373788594; called by muse, mutect2, varscan2
- ERICH3 | c.3169G>T p.A1057S | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as COSV100443948; called by muse, mutect2, varscan2
- F13B | c.508T>A p.F170I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV100803256; called by muse, mutect2
- F9 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV99496497; called by muse, mutect2
- FAT1 | c.11614C>T p.R3872* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs1342860045, COSV71674825; called by muse, mutect2, varscan2
- FSTL1 | c.207T>G p.N69K | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99820622; called by muse, mutect2, varscan2
- GRID1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201655919, COSV60017942; called by muse, mutect2, varscan2
- GRIN2B | c.4286C>T p.P1429L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.071); catalogued as rs1261054497, COSV101662998; called by muse, mutect2, varscan2
- GTPBP8 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.374); catalogued as COSV99868200; called by muse, mutect2, varscan2
- H2BC8 | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); catalogued as rs749610657, COSV55127778, COSV99773166; called by muse, mutect2, varscan2
- INPP4A | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as COSV99303261; called by muse, mutect2, varscan2
- IRF7 | c.1181G>A p.G394D (on ENST00000397566; = p.G381D on NM_001572.5) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1321391590, COSV99199852; called by muse, mutect2
- ITPKC | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99648624; called by muse, mutect2, varscan2
- KCNK18 | c.656C>G p.S219* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100572022, COSV57971966; called by muse, mutect2, varscan2
- KCNN2 | c.1534A>G p.T512A (on ENST00000264773; = p.T724A on NM_021614.4) | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1333419277, COSV99299401; called by muse, mutect2, varscan2
- KHSRP | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100382973; called by muse, mutect2, varscan2
- KIF5B | c.243A>G p.I81M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147256984; called by muse, mutect2, varscan2
- LMTK3 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV99540305; called by muse, mutect2, varscan2
- LRRC6 | c.1129T>A p.C377S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99137899; called by muse, mutect2, varscan2
- LRRC7 | c.99G>C p.E33D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV100200270; called by muse, mutect2
- MAGEA11 | c.234G>T p.R78S | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100290448, COSV60756977; called by muse, mutect2, varscan2
- MIB1 | c.2434G>C p.D812H | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.969); catalogued as COSV55088241, COSV99838598; called by muse, mutect2, varscan2
- MMP17 | c.293-2A>G p.X98_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100861897; called by muse, mutect2, varscan2
- MYO9B | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as rs1364884004, COSV68279309; called by muse, mutect2, varscan2
- NAP1L2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100999195; called by muse, mutect2, varscan2
- NEXMIF | c.3943G>T p.E1315* | Nonsense Mutation (SNP) | VAF 41/158 reads (26%) | catalogued as COSV99280373; called by muse, mutect2, varscan2
- NFATC2 | c.2735T>C p.I912T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs763306998, COSV101043912; called by muse, mutect2, varscan2
- NTRK3 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as COSV100446293; called by muse, mutect2, varscan2
- NUP155 | c.3196C>T p.R1066* (on ENST00000231498 / NM_153485.3; = p.R1007* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV51528924; called by muse, mutect2, varscan2
- OBP2A | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs760517173, COSV59790956, COSV59791163; called by muse, mutect2, varscan2
- OR2J2 | c.622G>T p.V208F | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV101013336; called by muse, mutect2, varscan2
- OR5H6 | c.343G>C p.V115L (on ENST00000642105; = p.V99L on NM_001005479.2) | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV101051765; called by muse, mutect2, varscan2
- PCDHB5 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.081); catalogued as COSV50671950; called by muse, mutect2, varscan2
- PCDHGB2 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs573308473, COSV53966534; called by mutect2, varscan2
- PCNX3 | c.4255G>A p.E1419K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100856258; called by muse, mutect2, varscan2
- PDZD8 | c.2945C>T p.T982M | Missense Mutation (SNP) | VAF 84/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs148717941; called by muse, mutect2, varscan2
- PEG3 | c.3579G>T p.M1193I | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV55644167, COSV99688353; called by muse, mutect2, varscan2
- PLA2G6 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.02); catalogued as rs778705470, COSV100140327; called by mutect2, varscan2
- POLR3A | c.4033G>T p.E1345* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100965606; called by muse, mutect2, varscan2
- PUS7L | c.628G>C p.V210L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV100786513; called by muse, mutect2, varscan2
- RIBC1 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 15/23 reads (65%) | catalogued as COSV51448996; called by muse, mutect2, varscan2
- ROCK1 | c.721A>G p.I241V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV101296328; called by muse, mutect2, varscan2
- SEMA3A | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV54886742; called by muse, mutect2, varscan2
- SH3TC2 | c.3500T>C p.V1167A | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.291); catalogued as COSV100101516; called by muse, mutect2, varscan2
- SLC25A43 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99474500; called by muse, mutect2, varscan2
- SLC8A1 | c.2537C>G p.S846* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100245527, COSV60491524; called by muse, mutect2, varscan2
- SPATA9 | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57224644; called by muse, mutect2, varscan2
- SYNE2 | c.8074A>G p.R2692G | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100647345; called by muse, mutect2, varscan2
- TBX20 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV101282368; called by muse, mutect2, varscan2
- TBX22 | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100960722; called by muse, mutect2, varscan2
- TMCO1 | c.548A>G p.N183S (on ENST00000612311 / NM_001256164.1; = p.N132S on NM_019026.6) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.159); catalogued as COSV100903128; called by muse, mutect2, varscan2
- TRHDE | c.1660T>G p.L554V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99670180; called by muse, mutect2, varscan2
- TRPM3 | c.734G>C p.R245P (on ENST00000357533 / NM_001366142.2; = p.R90P on NM_020952.6) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV100624473; called by muse, mutect2, varscan2
- TRPM6 | c.4132G>A p.D1378N | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.014); catalogued as COSV100666146; called by muse, mutect2, varscan2
- UAP1 | c.280+1G>T p.X94_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99617590; called by muse, mutect2, varscan2
- USP29 | c.902A>C p.Q301P | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99517947; called by muse, mutect2, varscan2
- WSCD1 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs769772044, COSV100496497; called by muse, mutect2, varscan2
- ZNF432 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 29/95 reads (31%) | catalogued as COSV99659178; called by muse, mutect2, varscan2
- ZSCAN1 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs751444550, COSV56606365; called by muse, mutect2, varscan2
- AKAP7 | c.715del p.I239* | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- EGR1 | c.250_254dup p.F86Afs*17 | Frame Shift Ins (INS) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- FAT1 | c.6998_7020del p.F2333Sfs*24 | Frame Shift Del (DEL) | VAF 18/184 reads (10%) | called by mutect2, pindel
- ABCA13 | c.1362G>A p.A454= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs927107670, COSV101330001; called by muse, mutect2, varscan2
- ABCA4 | c.2073C>T p.V691= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100933093; called by muse, mutect2, varscan2
- ADGRD1 | c.879C>T p.P293= | Silent (SNP) | VAF 46/179 reads (26%) | catalogued as rs778881478, COSV55449260; called by muse, mutect2, varscan2
- AMER2 | c.1527G>A p.P509= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV63437429; called by muse, mutect2, varscan2
- ARSI | c.1479C>T p.A493= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as rs141146390; called by muse, mutect2, varscan2
- ATG2A | c.1185C>T p.S395= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs767173132, COSV101034170; called by mutect2, varscan2
- BRINP1 | c.1860T>A p.R620= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as COSV99775081; called by muse, mutect2, varscan2
- CCDC125 | c.1158T>C p.P386= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV101143554; called by muse, mutect2, varscan2
- CDK3 | c.852G>A p.P284= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs150329289; called by muse, mutect2, varscan2
- CEP95 | c.2376T>C p.D792= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101616309; called by muse, mutect2, varscan2
- COL6A1 | c.339C>G p.L113= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100720101; called by muse, mutect2
- CRYBB3 | c.360G>A p.E120= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99309024; called by muse, mutect2, varscan2
- DHRS7 | c.939G>A p.G313= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV99381567; called by muse, mutect2, varscan2
- DNTTIP1 | c.234C>T p.I78= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99714507; called by muse, mutect2, varscan2
- EXTL1 | c.456A>G p.Q152= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs758644180, COSV100959091; called by muse, mutect2, varscan2
- FER1L6 | c.4258C>T p.L1420= | Silent (SNP) | VAF 44/205 reads (21%) | catalogued as COSV101205727; called by muse, mutect2, varscan2
- FNIP2 | c.450C>T p.Y150= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100032464; called by muse, mutect2, varscan2
- FYCO1 | c.2544C>T p.C848= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99945473; called by muse, mutect2, varscan2
- GRIK1 | c.9C>T p.H3= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs766297532, COSV58721304; called by muse, mutect2, varscan2
- KIR2DL1 | c.15C>T p.V5= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs1437769157, COSV52409696; called by muse, mutect2, varscan2
- KMT5B | c.2265C>T p.N755= | Silent (SNP) | VAF 60/218 reads (28%) | catalogued as COSV100430091; called by muse, mutect2, varscan2
- KRT74 | c.777G>T p.V259= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99977478; called by muse, mutect2, varscan2
- LAGE3 | c.198C>T p.S66= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV100635699; called by muse, mutect2, varscan2
- LGSN | c.1512C>T p.F504= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs1249872798, COSV101040437, COSV65727256; called by muse, mutect2, varscan2
- MALSU1 | c.36C>T p.A12= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99799867; called by muse, mutect2
- MDN1 | c.12054G>A p.L4018= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV101021106; called by muse, mutect2, varscan2
- MYH13 | c.1302C>T p.Y434= | Silent (SNP) | VAF 38/183 reads (21%) | catalogued as rs758813016, COSV52825585; called by muse, mutect2, varscan2
- MYO6 | c.2382G>A p.K794= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV100889339; called by muse, mutect2, varscan2
- OGT | c.2595G>A p.L865= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV101035320; called by muse, mutect2, varscan2
- OR51Q1 | c.630C>T p.I210= | Silent (SNP) | VAF 41/170 reads (24%) | catalogued as rs773847387, COSV56178359; called by muse, mutect2, varscan2
- PCDHB4 | c.120C>T p.S40= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV52021771, COSV52026855; called by muse, mutect2, varscan2
- PCED1A | c.363T>G p.L121= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV100642852; called by muse, mutect2
- PDILT | c.1465C>T p.L489= | Silent (SNP) | VAF 53/272 reads (19%) | catalogued as COSV100199280; called by muse, mutect2, varscan2
- PEX19 | c.156G>A p.K52= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV100926939; called by muse, mutect2, varscan2
- PLXNB2 | c.4884C>T p.V1628= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1190340649, COSV100833983; called by muse, mutect2, varscan2
- PNMA5 | c.336T>C p.D112= | Silent (SNP) | VAF 48/297 reads (16%) | catalogued as COSV62625961; called by muse, mutect2, varscan2
- PRAMEF1 | c.459C>T p.I153= | Silent (SNP) | VAF 74/302 reads (25%) | catalogued as COSV100179622; called by muse, mutect2, varscan2
- RFX6 | c.1761C>T p.D587= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as rs531536969, COSV60583452; called by muse, mutect2, varscan2
- RUNX1T1 | c.457C>T p.L153= (on ENST00000265814 / NM_001198628.1; = p.L126= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/126 reads (34%) | catalogued as COSV99751076; called by muse, mutect2, varscan2
- SLCO5A1 | c.2394C>T p.F798= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as COSV52661353; called by muse, mutect2, varscan2
- SPESP1 | c.930C>G p.L310= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99533660; called by muse, mutect2, varscan2
- SRMS | c.297C>T p.A99= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs531420290, COSV99421293; called by muse, varscan2
- TMEM132E | c.363G>A p.T121= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs541603154, COSV58694686; called by muse, mutect2, varscan2
- TMEM41B | c.180T>C p.I60= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100215651; called by muse, mutect2, varscan2
- TNRC6A | c.1488A>T p.P496= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV100169735; called by muse, mutect2, varscan2
- TP53BP2 | c.2109C>G p.L703= (on ENST00000343537 / NM_001031685.3; = p.L574= on NM_005426.2) | Silent (SNP) | VAF 48/178 reads (27%) | catalogued as COSV100636567; called by muse, mutect2, varscan2
- AL136982.4 | n.573G>A | RNA (SNP) | VAF 57/287 reads (20%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11991G>C | Intron (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- MIR656 | n.63T>C | RNA (SNP) | VAF 25/103 reads (24%) | catalogued as rs185468172; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559230 C>G | 5'Flank (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2, varscan2
- SNORD116-14 | n.42G>A | RNA (SNP) | VAF 27/183 reads (15%) | called by muse, mutect2, varscan2
